Somatic mutation profile of tumor specimen RC-B6SF-TBP1-A (aliquot RC-B6SF-TBP1-A-1-0-D-A94K-47) from RC case RC-B6SF, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 61.6 years (22,500 days).
Specimen RC-B6SF-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc04a787-6464-4d41-be35-71470a746d19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6SF-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6SF-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99b75727-fece-4839-9407-1891226aa92a

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- POTEJ | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.228); called by mutect2, varscan2
- REPIN1 | c.-338+74T>G | Intron (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
